Somatic mutation profile of tumor specimen MBCProject_3946_T1_WES (aliquot MBCProject_3946_T1_WES_1) from CMI case MBCProject_3946, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 49.7 years (18,137 days).
Specimen MBCProject_3946_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b0634b6-f876-439b-a92f-c3c9591b762e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3946_SALIVA (Saliva), aliquot MBCProject_3946_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f024442-8d97-46ea-9492-fb4ec3ebb793

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, 5'Flank 2, Frame Shift Del 2, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 76/144 reads (53%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 102/310 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, varscan2
- BST1 | c.618dup p.A207Cfs*4 | Frame Shift Ins (INS) | VAF 28/116 reads (24%) | catalogued as rs761650390; called by mutect2, varscan2
- CCER1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs777284354, COSV100726925, COSV62646542; called by muse, mutect2, varscan2
- CNTN5 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777608054, COSV54330472; called by muse, mutect2
- GOLGA3 | c.2417del p.T806Sfs*5 | Frame Shift Del (DEL) | VAF 40/152 reads (26%) | catalogued as COSV52634297; called by mutect2, pindel, varscan2
- GRIN2D | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV54379603; called by muse, mutect2, varscan2
- HSPG2 | c.10906G>A p.A3636T | Missense Mutation (SNP) | VAF 108/367 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs370883205; called by muse, mutect2, varscan2
- MROH2A | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV67680482; called by muse, mutect2, varscan2
- MYH9 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 124/251 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53382974; called by muse, mutect2, varscan2
- NLE1 | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs554861899; called by muse, mutect2, varscan2
- TMEM132B | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 86/349 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs202118018, COSV54768924; called by muse, mutect2, varscan2
- CDKN1B | c.295_305del p.C99Gfs*22 | Frame Shift Del (DEL) | VAF 94/382 reads (25%) | called by mutect2, varscan2
- CTC1 | c.1469A>G p.Q490R | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DHX29 | c.41C>G p.A14G | Missense Mutation (SNP) | VAF 193/590 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA8M | c.385A>T p.R129W | Missense Mutation (SNP) | VAF 68/406 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- KAT14 | c.1974T>G p.F658L | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- POLR2B | c.3049G>A p.D1017N | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- AGRN | c.5901G>A p.Q1967= | Silent (SNP) | VAF 24/252 reads (10%) | catalogued as rs1474940071; called by muse, mutect2
- C4orf54 | c.2358C>T p.D786= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as rs1161266049; called by muse, mutect2, varscan2
- DBX1 | c.549G>A p.L183= | Silent (SNP) | VAF 72/287 reads (25%) | called by muse, mutect2, varscan2
- DCTPP1 | c.93C>G p.L31= | Silent (SNP) | VAF 74/367 reads (20%) | called by muse, mutect2, varscan2
- GRIN2A | c.3861C>T p.S1287= | Silent (SNP) | VAF 142/711 reads (20%) | catalogued as rs1447951387; called by muse, mutect2, varscan2
- OPN4 | c.1050C>T p.Y350= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as rs751996931, COSV54116644; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23763A>G | Intron (SNP) | VAF 67/196 reads (34%) | called by muse, mutect2, varscan2
- STIP1 | chr11:64185866 A>G | 5'Flank (SNP) | VAF 86/342 reads (25%) | catalogued as rs975343062; called by muse, mutect2, varscan2
- ZNF559 | chr19:9324200 T>C | 5'Flank (SNP) | VAF 61/289 reads (21%) | catalogued as rs1165892942; called by muse, mutect2, varscan2
- ZNF833P | n.1200G>A | RNA (SNP) | VAF 84/257 reads (33%) | called by muse, mutect2, varscan2
